Somatic mutation profile of tumor specimen TCGA-AG-3894-01A (aliquot TCGA-AG-3894-01A-01W-1073-09) from TCGA case TCGA-AG-3894, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 65.6 years (23,954 days).
Specimen TCGA-AG-3894-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bb8f2584-dca4-4746-8e3d-374fe4a48b1c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AG-3894-10A (Blood Derived Normal), aliquot TCGA-AG-3894-10A-01W-1073-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f1e32efa-b949-4903-8670-94a189a3d70f

The open-access MAF lists 101 somatic variants for this specimen: 75 protein-altering or splice-affecting, 24 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 62, Silent 24, Nonsense Mutation 6, Frame Shift Del 3, Splice Region 2, Splice Site 1, Frame Shift Ins 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.646C>T p.R216* | Nonsense Mutation (SNP) | VAF 17/83 reads (20%) | hotspot (GDC flag); catalogued as rs62619935, CM992133, COSV57320867; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 69/178 reads (39%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- PCBP1 | c.305T>A p.L102Q | Missense Mutation (SNP) | VAF 11/24 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57850093, COSV57850258, COSV57850830; called by muse, mutect2, varscan2
- PEX1 | c.403C>T p.R135* | Nonsense Mutation (SNP) | VAF 50/95 reads (53%) | catalogued as rs201415996, COSV50395532; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ATRNL1 | c.3476C>T p.T1159M | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs782000658, COSV58079419, COSV58090880; called by muse, mutect2, varscan2
- C3orf20 | c.2110C>G p.P704A | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1474253548, COSV53783599; called by muse, mutect2, varscan2
- CACNG3 | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as COSV50065182, COSV99135432; called by muse, mutect2, varscan2
- CDH12 | c.180_181insC p.F61Lfs*45 | Frame Shift Ins (INS) | VAF 48/133 reads (36%) | catalogued as COSV66394728, COSV66436210; called by mutect2, pindel, varscan2
- CEP85L | c.1653A>T p.K551N | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV63821513; called by muse, mutect2, varscan2
- CFHR4 | c.1537+1G>A p.X513_splice (on ENST00000367416 / NM_001201551.2; = p.X267_splice on NM_006684.5) | Splice Site (SNP) | VAF 25/69 reads (36%) | catalogued as rs749419410; called by muse, mutect2, varscan2
- CHD9 | c.8105G>A p.G2702E (on ENST00000398510 / NM_001382353.1; = p.G2686E on NM_025134.7) | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT tolerated (0.65); PolyPhen benign (0.201); catalogued as COSV54608909; called by muse, mutect2, varscan2
- CNGA2 | c.289C>T p.R97C | Missense Mutation (SNP) | VAF 33/45 reads (73%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs141559818, COSV61703782; called by muse, mutect2, varscan2
- CREB3 | c.134C>G p.P45R | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.32); catalogued as rs376045014, COSV59205807; called by muse, mutect2, varscan2
- CYB5D1 | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.104); catalogued as rs766937014, COSV54679527, COSV99641722; called by muse, mutect2
- CYP4F11 | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.104); catalogued as rs770840051, COSV56125963; called by muse, mutect2, varscan2
- CYRIB | c.176C>A p.A59D | Missense Mutation (SNP) | VAF 62/160 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63118422; called by muse, mutect2, varscan2
- DBH | c.776C>A p.A259D | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.363); catalogued as COSV55040173; called by muse, mutect2
- DNER | c.397G>T p.E133* | Nonsense Mutation (SNP) | VAF 15/28 reads (54%) | catalogued as COSV59162579, COSV59172851; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.455G>C p.G152A | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated, low confidence (0.24); PolyPhen possibly damaging (0.542); catalogued as rs1158005982, COSV50051239; called by muse, mutect2, varscan2
- EDNRB | c.1304T>C p.L435P (on ENST00000377211 / NM_001201397.1; = p.L345P on NM_000115.5) | Missense Mutation (SNP) | VAF 41/133 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57520267; called by muse, mutect2, varscan2
- FAT4 | c.6464C>T p.A2155V | Missense Mutation (SNP) | VAF 49/142 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV58677049; called by muse, mutect2, varscan2
- FBXO15 | c.1331C>T p.P444L | Missense Mutation (SNP) | VAF 170/408 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs761515422, COSV54043808; called by muse, mutect2, varscan2
- FMNL2 | c.1256A>C p.K419T | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56492099; called by muse, mutect2, varscan2
- GAGE10 | c.88C>T p.Q30* | Nonsense Mutation (SNP) | VAF 126/344 reads (37%) | catalogued as COSV68163814; called by muse, mutect2, varscan2
- GALNT17 | c.317C>G p.A106G | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV100355907, COSV61153893; called by muse, mutect2, varscan2
- GNPTAB | c.229G>A p.V77I | Missense Mutation (SNP) | VAF 101/280 reads (36%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.923); catalogued as rs985184620, COSV54778162; called by muse, mutect2, varscan2
- GPR37 | c.659C>G p.A220G | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV58256039; called by muse, mutect2, varscan2
- GZMK | c.143G>A p.G48E | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.616); catalogued as COSV50244452; called by muse, mutect2, varscan2
- HOOK3 | c.101A>C p.D34A | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV56880709; called by muse, mutect2, varscan2
- HRH1 | c.997A>G p.T333A | Missense Mutation (SNP) | VAF 4/78 reads (5%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV101229069; called by muse, mutect2
- HTR3D | c.1171C>G p.P391A (on ENST00000382489 / NM_001163646.2; = p.P216A on NM_182537.3) | Missense Mutation (SNP) | VAF 44/106 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.07); catalogued as COSV61913492, COSV61913652; called by muse, mutect2, varscan2
- ICE2 | c.2298A>G p.Q766= | Splice Region (SNP) | VAF 35/113 reads (31%) | catalogued as rs1261428037, COSV55030434, COSV55032267; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1006C>T p.R336* | Nonsense Mutation (SNP) | VAF 93/105 reads (89%) | catalogued as COSV100781466, COSV61148187; called by muse, mutect2, varscan2
- ITK | c.497G>A p.R166Q | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as rs760650238, COSV70061019; called by muse, mutect2, varscan2
- KIAA1109 | c.1303A>C p.I435L | Missense Mutation (SNP) | VAF 81/186 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as COSV52666595; called by muse, mutect2, varscan2
- KLRB1 | c.500G>A p.W167* | Nonsense Mutation (SNP) | VAF 26/72 reads (36%) | catalogued as rs1285108310, COSV57589371; called by muse, mutect2
- LRCH4 | c.848+2dup | Splice Region (INS) | VAF 15/37 reads (41%) | catalogued as rs1260794262; called by mutect2, pindel, varscan2
- MRPS21 | c.242C>T p.A81V | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV58413824; called by muse, mutect2, varscan2
- MUC17 | c.2312C>G p.P771R | Missense Mutation (SNP) | VAF 198/492 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV100074449, COSV60283660; called by muse, mutect2, varscan2
- NEUROD6 | c.951C>G p.D317E | Missense Mutation (SNP) | VAF 50/119 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV51770666; called by muse, mutect2, varscan2
- NYAP2 | c.1375G>A p.A459T | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.41); PolyPhen benign (0.267); catalogued as COSV56001420; called by muse, mutect2, varscan2
- OR51B4 | c.271G>T p.A91S | Missense Mutation (SNP) | VAF 57/149 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV66516991, COSV66517465; called by muse, mutect2, varscan2
- OVCH1 | c.1726G>A p.A576T | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT tolerated (0.35); PolyPhen benign (0.366); catalogued as rs768768201, COSV58961050; called by muse, mutect2, varscan2
- PCDH9 | c.3155C>T p.T1052M (on ENST00000377865 / NM_203487.3; = p.T1018M on NM_020403.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs150709677, COSV60601477; called by muse, mutect2, varscan2
- PCDHB13 | c.1605C>G p.D535E | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV53394468, COSV53398134; called by muse, mutect2, varscan2
- PCDHB16 | c.1966G>A p.A656T | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV53359761; called by muse, varscan2
- PCDHGB7 | c.989G>A p.R330Q | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs770294020, COSV53919060, COSV53945961; called by muse, mutect2, varscan2
- PLS1 | c.731T>A p.I244N | Missense Mutation (SNP) | VAF 111/263 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.235); catalogued as COSV61833243; called by muse, mutect2, varscan2
- PNPT1 | c.1100T>A p.L367H | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53176522; called by muse, mutect2, varscan2
- PPP6R3 | c.2533G>A p.A845T (on ENST00000393800 / NM_001352375.2; = p.A765T on NM_018312.5) | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs199837553; called by muse, mutect2, varscan2
- PRICKLE1 | c.1451C>T p.A484V | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV58205346; called by muse, mutect2, varscan2
- PTPRM | c.1432G>T p.D478Y | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59850399; called by muse, mutect2, varscan2
- PTPRN | c.2348C>T p.T783M | Missense Mutation (SNP) | VAF 55/122 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747918524, COSV55346645; called by muse, mutect2, varscan2
- SAMD9L | c.3320G>A p.R1107H | Missense Mutation (SNP) | VAF 193/433 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs369116471; called by muse, mutect2, varscan2
- SCNN1G | c.1691G>A p.R564H | Missense Mutation (SNP) | VAF 52/102 reads (51%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs762732326, COSV55597490; called by muse, mutect2, varscan2
- SMC4 | c.1959A>T p.E653D | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV61003847; called by muse, mutect2, varscan2
- SPON1 | c.2212C>T p.R738W | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs782356380, COSV59958839; called by muse, mutect2, varscan2
- ST8SIA3 | c.892C>T p.R298W | Missense Mutation (SNP) | VAF 8/37 reads (22%) | PolyPhen probably damaging (1); catalogued as rs1239830419, COSV60653668; called by muse, varscan2
- SYCP1 | c.2270A>T p.K757I | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.712); catalogued as COSV65695629; called by muse, mutect2, varscan2
- SYNE1 | c.23090C>T p.S7697L (on ENST00000367255 / NM_182961.4; = p.S7626L on NM_033071.3) | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.74); catalogued as rs751252119, COSV54938281; called by muse, mutect2, varscan2
- TIGD7 | c.266A>C p.Q89P | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.988); catalogued as COSV51915642; called by muse, mutect2, varscan2
- TOX4 | c.955A>G p.M319V | Missense Mutation (SNP) | VAF 97/275 reads (35%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs754892125, COSV52968082; called by muse, mutect2, varscan2
- TRMT2B | c.869G>A p.S290N | Missense Mutation (SNP) | VAF 4/76 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.407); catalogued as COSV100105384; called by muse, mutect2
- TUBB8 | c.935C>T p.T312M | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.698); catalogued as rs559882106, COSV59115129; called by muse, mutect2, varscan2
- TULP2 | c.1207C>T p.R403W | Missense Mutation (SNP) | VAF 58/162 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769812574, COSV55477350; called by muse, mutect2, varscan2
- UHRF1BP1 | c.1144C>T p.R382C | Missense Mutation (SNP) | VAF 44/170 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs774161694, COSV51953966; called by muse, mutect2, varscan2
- USP18 | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 48/99 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.122); catalogued as COSV53173039; called by muse, mutect2, varscan2
- VNN1 | c.791C>A p.A264E | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV63389563; called by muse, mutect2, varscan2
- ZFHX4 | c.4983A>C p.K1661N | Missense Mutation (SNP) | VAF 161/340 reads (47%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.832); catalogued as COSV50644164; called by muse, mutect2, varscan2
- ZNF280A | c.820G>C p.V274L | Missense Mutation (SNP) | VAF 10/236 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as COSV57479913, COSV57481695; called by muse, mutect2
- ZNF3 | c.132G>C p.K44N | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.987); catalogued as rs1429971541, COSV52795436; called by muse, mutect2, varscan2
- ZNF43 | c.2409A>C p.Q803H | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV61683331; called by muse, mutect2, varscan2
- ABCF2 | c.285del p.H96Mfs*13 | Frame Shift Del (DEL) | VAF 20/55 reads (36%) | called by mutect2, pindel, varscan2
- APC | c.4124_4125del p.H1375Lfs*10 | Frame Shift Del (DEL) | VAF 30/134 reads (22%) | called by pindel, varscan2
- GAD2 | c.1501_1524delinsT p.H501Yfs*12 | Frame Shift Del (DEL) | VAF 61/256 reads (24%) | called by pindel, varscan2*
- ACLY | c.726C>T p.F242= | Silent (SNP) | VAF 26/62 reads (42%) | catalogued as rs782400219, COSV61249818; called by muse, mutect2, varscan2
- AMER2 | c.174G>A p.P58= | Silent (SNP) | VAF 15/17 reads (88%) | catalogued as COSV63436734; called by muse, mutect2, varscan2
- BTG4 | c.627T>A p.P209= | Silent (SNP) | VAF 33/123 reads (27%) | catalogued as COSV63635458; called by muse, mutect2, varscan2
- CACNA2D2 | c.885C>T p.I295= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV56561838; called by muse, mutect2, varscan2
- COL12A1 | c.2352A>G p.P784= | Silent (SNP) | VAF 148/392 reads (38%) | catalogued as COSV59392246; called by muse, mutect2, varscan2
- COL6A5 | c.6243C>G p.V2081= (on ENST00000312481; = p.V2077= on NM_153264.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/109 reads (5%) | catalogued as rs1347050622, COSV99593309; called by muse, mutect2
- CTSE | c.348G>T p.T116= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as rs149390455, COSV63060126; called by muse, mutect2, varscan2
- ELOA2 | c.204C>T p.D68= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as COSV55296010; called by muse, mutect2, varscan2
- FGF18 | c.228C>T p.R76= | Silent (SNP) | VAF 16/34 reads (47%) | catalogued as rs760722261, COSV51125634; called by muse, mutect2, varscan2
- HS6ST3 | c.861G>T p.G287= | Silent (SNP) | VAF 50/94 reads (53%) | catalogued as COSV65005069, COSV65009492; called by muse, mutect2, varscan2
- KRT26 | c.564C>T p.A188= | Silent (SNP) | VAF 44/124 reads (35%) | catalogued as rs759949567, COSV59413431; called by muse, mutect2, varscan2
- LOXL2 | c.1155C>T p.I385= | Silent (SNP) | VAF 25/61 reads (41%) | catalogued as rs199848147, COSV66690812; called by muse, mutect2, varscan2
- MUC16 | c.31908C>A p.V10636= | Silent (SNP) | VAF 209/488 reads (43%) | catalogued as rs779800465, COSV67454700; called by muse, mutect2
- OR5D18 | c.789C>G p.P263= | Silent (SNP) | VAF 49/130 reads (38%) | catalogued as rs1336556613, COSV61736608; called by muse, mutect2
- PCDHA12 | c.183G>A p.P61= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV100250737; called by muse, mutect2, varscan2
- PLEKHG7 | c.1599C>T p.S533= | Silent (SNP) | VAF 26/68 reads (38%) | catalogued as COSV60821373; called by muse, mutect2, varscan2
- PLXNA4 | c.4176C>T p.T1392= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as rs369419660; called by muse, mutect2, varscan2
- SAAL1 | c.1134A>G p.T378= | Silent (SNP) | VAF 24/80 reads (30%) | catalogued as COSV55514998; called by muse, mutect2, varscan2
- SALL1 | c.642G>A p.A214= | Silent (SNP) | VAF 27/92 reads (29%) | catalogued as rs762501097, COSV51755193; called by muse, mutect2
- SLC17A9 | c.1035C>T p.S345= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV64846993; called by muse, mutect2, varscan2
- SLC26A4 | c.471C>T p.P157= | Silent (SNP) | VAF 52/140 reads (37%) | catalogued as rs557892300, COSV55915240; called by muse, mutect2, varscan2
- STOX2 | c.2703C>T p.S901= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as rs1462517081, COSV57850292; called by muse, mutect2, varscan2
- TAS2R3 | c.151C>T p.L51= | Silent (SNP) | VAF 187/485 reads (39%) | catalogued as rs1563035184, COSV56091752; called by muse, mutect2, varscan2
- TTN | c.12900T>C p.S4300= (on ENST00000591111; = p.S4254= on NM_003319.4) | Silent (SNP) | VAF 34/114 reads (30%) | catalogued as COSV59955131; called by muse, mutect2, varscan2
- DEFB119 | c.61+1273C>T | Intron (SNP) | VAF 83/293 reads (28%) | catalogued as rs150443667; called by muse, mutect2, varscan2
- HMGN2P46 | n.1136C>T | RNA (SNP) | VAF 77/234 reads (33%) | catalogued as rs1176313315; called by muse, mutect2, varscan2
